Somatic mutation profile of tumor specimen MMRF_1671_4_BM_CD138pos (aliquot MMRF_1671_4_BM_CD138pos_T1_KHS5U_L15695) from MMRF case MMRF_1671, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,073 days).
Specimen MMRF_1671_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3367c243-130a-415e-bd76-fae57ee7973c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1671_4_PB_WBC (Blood Derived Normal), aliquot MMRF_1671_4_PB_WBC_C3_KHS5U_L15743; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b88c2eee-a212-457d-b26b-365b54e1212e

The open-access MAF lists 132 somatic variants for this specimen: 65 protein-altering or splice-affecting, 12 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 29, Intron 14, Silent 12, Splice Site 5, Nonsense Mutation 4, 5'UTR 4, 5'Flank 3, 3'Flank 3, Frame Shift Del 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 121/245 reads (49%) | catalogued as rs769676029, COSV59592240; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ELANE | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as rs1555710005, CS091635, CS112156, CS993231; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs794728325, CM091205, CM091206, CS013965, COSV57313335; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 37/77 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLDN14 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs920191385; called by muse, mutect2
- COL6A2 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373392391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSPG5 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751401533; called by muse, mutect2, varscan2
- DCHS1 | c.4252C>T p.R1418W | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs749199604; called by muse, mutect2, varscan2
- DDX60 | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs778995813; called by muse, mutect2, varscan2
- DGKQ | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs753197344, COSV56615807; called by muse, mutect2, varscan2
- EIF3E | c.661_664del p.V221Sfs*36 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs762916048; called by pindel, varscan2
- EPHA4 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as rs1346215997; called by muse, mutect2, varscan2
- EPX | c.1121-1G>A p.X374_splice | Splice Site (SNP) | VAF 62/118 reads (53%) | catalogued as COSV56598256; called by muse, mutect2, varscan2
- FAT3 | c.4139T>G p.I1380S | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV53070857; called by muse, mutect2, varscan2
- FREM2 | c.2676G>T p.L892F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV99748718; called by muse, mutect2, varscan2
- GPR142 | c.1254C>G p.S418R | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs368187784; called by muse, mutect2, varscan2
- HIVEP3 | c.3382G>A p.V1128I | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs540145704, COSV56014541; called by muse, mutect2, varscan2
- HIVEP3 | c.2537A>G p.K846R | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56010537; called by muse, mutect2
- HMX1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1336325306; called by muse, mutect2, varscan2
- IGKV4-1 | c.68T>A p.V23E | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs772165006; called by muse, mutect2, varscan2
- IGLV3-1 | c.146A>T p.K49I | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs61731694; called by muse, varscan2
- KRT3 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546099163, COSV58815743; called by muse, varscan2
- LHX9 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 114/394 reads (29%) | catalogued as COSV100435640; called by muse, mutect2, varscan2
- LRRC3C | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs574965380; called by muse, mutect2
- NCAPH2 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752146981, COSV52687158; called by muse, mutect2, varscan2
- NCOA1 | c.4155+1G>T p.X1385_splice | Splice Site (SNP) | VAF 82/182 reads (45%) | catalogued as rs769235879; called by muse, mutect2, varscan2
- SLFN12L | c.535G>T p.A179S (on ENST00000260908 / NM_001363830.1; = p.A197S on NM_001195790.1) | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV99610132; called by muse, mutect2
- SNX7 | c.505A>G p.M169V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1007806145; called by muse, mutect2
- SPATA31E1 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs1184361142; called by muse, mutect2, varscan2
- TEP1 | c.3867+2T>G p.X1289_splice | Splice Site (SNP) | VAF 83/196 reads (42%) | catalogued as COSV52993602; called by muse, mutect2, varscan2
- VWA3B | c.2909G>T p.R970L | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV68246151; called by muse, mutect2, varscan2
- ZNF33B | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63942798; called by muse, mutect2
- AHNAK | c.10207T>A p.F3403I | Missense Mutation (SNP) | VAF 172/372 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARMC5 | c.1371G>C p.R457S | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- CCR8 | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 23/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDK13 | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CFAP47 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DKK2 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- DPY19L1 | c.1150T>G p.F384V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPHB1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FBXO30 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 145/309 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCK | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HELZ2 | c.1964_1990del p.R655_H663del (on ENST00000467148 / NM_001037335.2; = p.R86_H94del on NM_033405.3) | In Frame Del (DEL) | VAF 38/149 reads (26%) | called by mutect2, pindel
- IGHV2-70D | c.145A>C p.S49R | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, varscan2
- KDM3B | c.5187T>G p.N1729K | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LKAAEAR1 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- MED12L | c.5746G>T p.A1916S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); called by muse, mutect2
- MTFR1 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2
- MYO16 | c.1520G>A p.S507N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2
- NKAP | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 86/110 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- NTRK3 | c.1229-2A>C p.X410_splice | Splice Site (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- NUFIP2 | c.843_849del p.Y282Lfs*27 | Frame Shift Del (DEL) | VAF 83/204 reads (41%) | called by mutect2, pindel, varscan2
- PKHD1 | c.6635C>A p.A2212D | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PLBD1 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.499); called by muse, mutect2
- QRFPR | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- RAD51AP2 | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.053); called by muse, mutect2
- RHEBL1 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RYR1 | c.3163C>T p.P1055S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SERPINA6 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- STK32A | c.856T>G p.W286G | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SYT4 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 145/359 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM9 | c.2042C>A p.P681H | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR59 | c.1270A>T p.N424Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2
- ZNF18 | c.1572C>A p.H524Q | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF462 | c.3620G>A p.G1207E | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP45 | c.492C>T p.I164= | Silent (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- BCCIP | c.51G>T p.P17= | Silent (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- CPA4 | c.1014G>A p.A338= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs577880214; called by muse, mutect2, varscan2
- CRACDL | c.607C>T p.L203= | Silent (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- EVC | c.1074C>T p.C358= | Silent (SNP) | VAF 71/136 reads (52%) | catalogued as rs921573510, COSV53832080; called by muse, mutect2, varscan2
- KCNB2 | c.447C>T p.N149= | Silent (SNP) | VAF 129/276 reads (47%) | catalogued as rs755305477, COSV101578734, COSV73048698; called by muse, mutect2, varscan2
- NTRK2 | c.2103G>T p.V701= (on ENST00000323115 / NM_001369534.1; = p.V717= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 92/215 reads (43%) | called by muse, mutect2, varscan2
- PEMT | c.282C>T p.L94= | Silent (SNP) | VAF 84/209 reads (40%) | catalogued as rs753328073; called by muse, mutect2, varscan2
- SYNC | c.186G>A p.E62= | Silent (SNP) | VAF 148/316 reads (47%) | catalogued as COSV65131234; called by muse, mutect2, varscan2
- TRAPPC5 | c.438C>T p.I146= | Silent (SNP) | VAF 111/276 reads (40%) | catalogued as rs1388314692, COSV58039962; called by muse, mutect2, varscan2
- TTN | c.99648G>A p.L33216= (on ENST00000591111; = p.L25792= on NM_003319.4) | Silent (SNP) | VAF 80/159 reads (50%) | called by muse, mutect2, varscan2
- ZNF510 | c.54C>T p.G18= | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as COSV56296644; called by muse, mutect2, varscan2
- ADCY1 | c.1605+2212C>G | Intron (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- AKAP1 | c.1714+809A>G | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- AL132796.2 | n.648C>G | RNA (SNP) | VAF 88/199 reads (44%) | called by muse, mutect2, varscan2
- ANKIB1 | c.*1033A>T | 3'UTR (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- ARL5B | c.*680G>A | 3'UTR (SNP) | VAF 58/150 reads (39%) | called by muse, mutect2, varscan2
- BNIPL | c.*341C>T | 3'UTR (SNP) | VAF 18/50 reads (36%) | catalogued as rs748564594; called by muse, mutect2, varscan2
- CCDC171 | c.*445C>T | 3'UTR (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- CCDC68 | chr18:54903648 G>T | 3'Flank (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- CDHR1 | c.1783-38C>T | Intron (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137018802 G>T | 3'Flank (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- CLPTM1 | c.72+148C>T | Intron (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- DNASE1L3 | chr3:58211173 C>G | 5'Flank (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- DSC2 | c.*174C>A | 3'UTR (SNP) | VAF 43/80 reads (54%) | called by muse, mutect2, varscan2
- EDNRA | c.*2278C>T | 3'UTR (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- GET4 | c.235-54C>T | Intron (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- GSTM3 | c.*1688G>A | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- GVINP1 | n.7494C>T | RNA (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- HLA-DMA | c.88+506G>A | Intron (SNP) | VAF 10/162 reads (6%) | catalogued as rs55750436; called by muse, mutect2
- HOXC5 | c.*42C>A | 3'UTR (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- LCORL | c.*1967T>G | 3'UTR (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- LINC02203 | c.-788+471G>T | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- MAGI2 | c.*1357G>T | 3'UTR (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- MEIS1 | c.240-275G>A | Intron (SNP) | VAF 11/255 reads (4%) | called by muse, mutect2
- NEUROD6 | c.*294G>A | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- NIBAN1 | c.*3919T>C | 3'UTR (SNP) | VAF 267/443 reads (60%) | called by muse, mutect2, varscan2
- PAN2 | c.*631G>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- PCDH15 | c.*229G>A | 3'UTR (SNP) | VAF 36/82 reads (44%) | catalogued as rs974421099; called by muse, mutect2, varscan2
- PCK1 | c.406+139T>A | Intron (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- PKNOX2 | c.*661C>T | 3'UTR (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- POR | c.-5+11T>A | Intron (SNP) | VAF 54/142 reads (38%) | called by muse, mutect2, varscan2
- POU2F2 | chr19:42089640 C>T | 3'Flank (SNP) | VAF 87/182 reads (48%) | called by muse, varscan2
- PPM1A | c.*4742G>A | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- PRPF40B | chr12:49623543 C>A | 5'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- PTPN13 | c.4149+15G>A | Intron (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- PYGL | c.-52G>A | 5'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2
- RFK | c.-223G>C | 5'UTR (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- RFT1 | c.-8C>T | 5'UTR (SNP) | VAF 83/155 reads (54%) | catalogued as rs766568297; called by muse, mutect2, varscan2
- RPL31 | c.*106C>T | 3'UTR (SNP) | VAF 184/406 reads (45%) | called by muse, mutect2, varscan2
- SEMA3C | c.*1195G>A | 3'UTR (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- SFMBT2 | c.*2834T>G | 3'UTR (SNP) | VAF 76/176 reads (43%) | called by muse, mutect2, varscan2
- SHF | c.303+154C>G | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- SNX20 | c.*1239A>G | 3'UTR (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- TAFA5 | c.*1701G>A | 3'UTR (SNP) | VAF 39/91 reads (43%) | catalogued as rs1241119143; called by muse, mutect2, varscan2
- TMEM185A | c.*847T>C | 3'UTR (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- TMEM25 | c.*449T>G | 3'UTR (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- TMF1 | c.*2861T>C | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- TMSB4X | c.-78T>C | 5'UTR (SNP) | VAF 123/140 reads (88%) | called by muse, mutect2, varscan2
- TRERF1 | c.*2994C>A | 3'UTR (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- TRIM14 | c.*788T>C | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- TRIM58 | c.*430C>T | 3'UTR (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- UNC5C | c.775+2033A>C | Intron (SNP) | VAF 84/137 reads (61%) | called by muse, mutect2, varscan2
- VCP | chr9:35072721 T>C | 5'Flank (SNP) | VAF 62/143 reads (43%) | catalogued as rs527975908; called by muse, mutect2, varscan2
- XPOT | c.*1318G>A | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- ZFC3H1 | c.*239C>T | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- ZNF382 | c.140-95A>G | Intron (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
